Somatic mutation profile of tumor specimen 0DVVKI from CCDI case PBCITS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 16.3 years (5,938 days).
Specimen 0DVVKI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4c72a17-1e7a-4514-a9c8-ae7d1a753438.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVVLY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc621cf6-94b8-4fbe-aea2-aa90d0bbbd16

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIBAR2 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 91/225 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775489646; called by muse, mutect2, varscan2
- NRK | c.1409G>C p.R470P | Missense Mutation (SNP) | VAF 51/353 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV54591426; called by muse, mutect2, varscan2
- SCRIB | c.1703C>T p.T568M | Missense Mutation (SNP) | VAF 105/272 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs761006834, COSV100254118; called by muse, mutect2, varscan2
- SV2C | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 163/454 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs748677235, COSV59218804, COSV59227560; called by muse, mutect2, varscan2
- ZXDB | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as COSV66492887; called by muse, mutect2
- SYNE1 | c.19595G>T p.G6532V (on ENST00000367255 / NM_182961.4; = p.G6461V on NM_033071.3) | Missense Mutation (SNP) | VAF 62/495 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.408); called by muse, varscan2
- PTPRF | c.2119+42C>A | Intron (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
